Gene-level copy-number profile of specimen HCM-SANG-1084-C15-85A-01D-A80T-32 from HCMI case HCM-SANG-1084-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: G3.
Specimen HCM-SANG-1084-C15-85A-01D-A80T-32: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d607b4eb-7408-4f4b-a162-d0cee537fc8f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-1084-C15-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,749 have no estimate.
https://portal.gdc.cancer.gov/files/07b85302-7c64-4fa4-a333-b0e27c12ebde

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 695; copy number 2: 19,100; copy number 3: 26,230; copy number 4: 10,077; copy number 5: 1,330; copy number 6: 1,369; copy number 7: 7; copy number 9: 9; copy number 10: 8; copy number 21: 37; copy number 22: 10; copy number 24: 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 73 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:66,682,497–66,958,386, 10 genes, copy number 22: SPTBN2, RN7SL12P, C11orf80, C1QBPP2, FTLP6, RCE1, PC, LRFN4, RNU7-23P, MIR3163.
- chr11:68,261,338–68,449,275, 2 genes, copy number 24: C11orf24, LRP5.
- chr11:69,641,156–71,252,577, 37 genes, copy number 21: CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN, SHANK2, AP001271.1, AP001271.2, SHANK2-AS1, SHANK2-AS2, Y_RNA, AP000590.1, SHANK2-AS3, MIR3664, AP003783.1.
- chr11:86,302,211–86,765,467, 9 genes, copy number 7–9: HIKESHI, RN7SL225P, CCDC81, AP001831.1, PTP4A1P6, AP001148.1, ME3, AP003059.1, AP003059.2.
- chr11:124,752,583–124,936,412, 13 genes, copy number 9–10: ESAM, AP000866.2, MSANTD2, AP000866.6, AP000866.3, AP000866.1, AP000866.4, ROBO3, AP003501.1, ROBO4, AP003501.2, HEPACAM, HEPN1.
- chr20:37,251,082–37,317,260, 2 genes, copy number 7: GHRH, MANBAL.

Autosomal genes at a single copy (total copy number 1): 342. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
